Somatic mutation profile of tumor specimen 0DUNP7 from CCDI case PBCLGZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.5 years (3,120 days).
Specimen 0DUNP7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b426d8f-1ed2-4843-9177-5ea498dc369f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUNP1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5338b13d-1ee6-4580-9372-be3268608454

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 3, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 205/461 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 315/736 reads (43%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAM30 | c.1441G>A p.V481I | Missense Mutation (SNP) | VAF 270/611 reads (44%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.658); catalogued as rs775753022, COSV65561216; called by muse, mutect2, varscan2
- CHRDL1 | c.632G>A p.R211Q (on ENST00000372045; = p.R217Q on NM_145234.4) | Missense Mutation (SNP) | VAF 310/696 reads (45%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.968); catalogued as rs920527397, COSV54324326; called by muse, mutect2, varscan2
- DNAH3 | c.8687G>A p.R2896H | Missense Mutation (SNP) | VAF 111/264 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748512714, COSV54519440; called by muse, mutect2, varscan2
- NEB | c.6482G>A p.R2161H | Missense Mutation (SNP) | VAF 407/858 reads (47%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as rs373778424; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARID1B | c.4799del p.V1600Efs*8 | Frame Shift Del (DEL) | VAF 321/370 reads (87%) | called by mutect2, varscan2
- DNAH11 | c.9983C>A p.A3328D | Missense Mutation (SNP) | VAF 131/712 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- STARD9 | c.2820G>T p.Q940H | Missense Mutation (SNP) | VAF 208/436 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- XPO5 | c.1810G>A p.A604T | Missense Mutation (SNP) | VAF 197/217 reads (91%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GALNT2 | c.1575C>T p.I525= | Silent (SNP) | VAF 195/516 reads (38%) | catalogued as rs778844648, COSV64193656; called by muse, mutect2
- MTMR3 | c.1860C>T p.A620= | Silent (SNP) | VAF 183/416 reads (44%) | called by muse, mutect2, varscan2
- OR52R1 | c.111G>A p.T37= | Silent (SNP) | VAF 215/473 reads (45%) | catalogued as rs773610816; called by muse, mutect2, varscan2
- SLC16A13 | c.200-40C>A | Intron (SNP) | VAF 62/130 reads (48%) | catalogued as rs1394790647; called by muse, mutect2, varscan2
